Somatic mutation profile of tumor specimen TCGA-E1-A7YS-01A (aliquot TCGA-E1-A7YS-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 71.6 years (26,159 days).
Specimen TCGA-E1-A7YS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cf2776e-de29-47ff-8f07-43706231a1c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YS-10A (Blood Derived Normal), aliquot TCGA-E1-A7YS-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec1fbcec-5938-49e8-b2e0-130bda402f85

The open-access MAF lists 58 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Splice Site 3, Frame Shift Del 2, Splice Region 2, 3'UTR 1, Intron 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 51/94 reads (54%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 46/106 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP8B3 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745956143, COSV100034738; called by muse, varscan2
- CALHM5 | c.743A>C p.N248T | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.844); catalogued as COSV100635646; called by muse, mutect2, varscan2
- CAMK1 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs752906254, COSV99844859; called by muse, varscan2
- CNOT2 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.564); catalogued as COSV99972901; called by muse, mutect2, varscan2
- CNTN1 | c.2980+3_2980+6del p.X994_splice | Splice Site (DEL) | VAF 51/85 reads (60%) | catalogued as rs1180265636; called by mutect2, pindel, varscan2
- DGKE | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401113; called by muse, mutect2, varscan2
- DHX57 | c.2752A>T p.T918S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV99769785; called by muse, mutect2, varscan2
- EDC3 | c.165-2A>T p.X55_splice | Splice Site (SNP) | VAF 51/56 reads (91%) | catalogued as COSV100166095, COSV59339273; called by muse, mutect2, varscan2
- FER1L6 | c.2857G>C p.V953L | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV101206097, COSV67552189; called by muse, mutect2, varscan2
- GABRA2 | c.1018A>G p.R340G | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100734635; called by muse, mutect2, varscan2
- GDI2 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV101200797; called by muse, mutect2, varscan2
- GFPT1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as COSV100622950; called by muse, mutect2, varscan2
- GOLGA3 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.32); catalogued as rs200254047, COSV99212301; called by muse, mutect2, varscan2
- GPBAR1 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs927173480, COSV50307704; called by muse, mutect2, varscan2
- KLB | c.2371G>T p.A791S | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.73); PolyPhen benign (0.318); catalogued as COSV99962374; called by muse, mutect2, varscan2
- LILRB1 | c.1800G>A p.R600= (on ENST00000427581; = p.R550= on NM_006669.6) | Splice Region (SNP) | VAF 25/36 reads (69%) | catalogued as COSV100207613; called by muse, mutect2, varscan2
- LTN1 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139463338; called by muse, mutect2, varscan2
- MAEL | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1417988501, COSV100774765; called by muse, mutect2, varscan2
- MFSD13A | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV99487983; called by muse, mutect2, varscan2
- MIS18BP1 | c.1350A>G p.G450= | Splice Region (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100173163; called by muse, mutect2, varscan2
- MMP12 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV58261047; called by muse, mutect2, varscan2
- OR2B3 | c.486G>T p.L162F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as COSV101013831; called by muse, mutect2, varscan2
- OR5H2 | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100788793; called by muse, mutect2, varscan2
- PCLO | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs201668310; called by muse, mutect2, varscan2
- PIK3CD | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.718); catalogued as COSV100740361; called by muse, mutect2, varscan2
- PRRX2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178504612, COSV100991196; called by muse, mutect2, varscan2
- PTPN21 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60847284; called by muse, mutect2, varscan2
- RFX3 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100175558; called by muse, mutect2, varscan2
- SAGE1 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT tolerated (0.57); PolyPhen benign (0.329); catalogued as rs782681413, COSV61016346; called by muse, mutect2, varscan2
- SAMD9L | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs746980471, COSV59080846; called by muse, mutect2
- SEC31B | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV100947405; called by muse, mutect2
- SERPINB10 | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 84/135 reads (62%) | catalogued as COSV99449530; called by muse, mutect2, varscan2
- SRRM4 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as COSV99939039; called by muse, mutect2, varscan2
- STK31 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV100669776; called by muse, mutect2, varscan2
- TRIM43 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs751140237, COSV55528559, COSV99720084; called by muse, mutect2, varscan2
- TRMT2B | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV100105569; called by muse, mutect2, varscan2
- TTN | c.28414G>T p.D9472Y (on ENST00000591111; = p.D8545Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | PolyPhen probably damaging (0.939); catalogued as COSV100623064; called by muse, mutect2
- ZBTB20 | c.1838G>A p.R613H (on ENST00000474710 / NM_001164342.2; = p.R540H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100614671; called by muse, mutect2, varscan2
- ZNF689 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236880597, COSV99788091; called by muse, mutect2, varscan2
- AGO2 | c.1612_1613del p.T538Gfs*135 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by pindel, varscan2
- GDA | c.123+2_123+5del p.X41_splice | Splice Site (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- NAE1 | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.022); called by mutect2, varscan2
- NAE1 | c.631_633dup p.H211dup | In Frame Ins (INS) | VAF 20/45 reads (44%) | called by mutect2, pindel, varscan2
- OR4A16 | c.700del p.A234Pfs*35 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- CHD5 | c.2982C>T p.N994= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV99314449; called by muse, mutect2
- EIF4G1 | c.4002C>T p.P1334= (on ENST00000346169 / NM_198241.3; = p.P1139= on NM_004953.5) | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as COSV100072136; called by muse, mutect2, varscan2
- GREB1 | c.2196G>A p.K732= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV99303439; called by muse, mutect2
- HOXB4 | c.354G>A p.P118= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100203809; called by muse, mutect2, varscan2
- OR5B2 | c.474T>C p.I158= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100222926; called by muse, mutect2, varscan2
- PRRC2B | c.1326C>T p.S442= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs1345871309, COSV100622030; called by muse, mutect2, varscan2
- SART1 | c.48G>T p.T16= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100409109, COSV56714212; called by muse, mutect2
- SMARCAD1 | c.216A>G p.P72= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100759000; called by muse, mutect2, varscan2
- TGM2 | c.1146C>T p.G382= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs541717032, COSV63932289; called by muse, mutect2, varscan2
- TRIM24 | c.1629C>T p.N543= (on ENST00000343526 / NM_015905.3; = p.N509= on NM_003852.4) | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as COSV100631113; called by muse, mutect2, varscan2
- SLC12A3 | c.2419+24G>A | Intron (SNP) | VAF 36/72 reads (50%) | catalogued as rs754322406, COSV99344557; called by muse, mutect2, varscan2
- SLC35A3 | c.*637G>A | 3'UTR (SNP) | VAF 17/33 reads (52%) | catalogued as rs749734512, COSV100924691; ClinVar: likely benign; called by muse, varscan2
